Somatic mutation profile of tumor specimen TCGA-BR-4184-01A (aliquot TCGA-BR-4184-01A-01D-1126-08) from TCGA case TCGA-BR-4184, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 70.7 years (25,816 days).
Specimen TCGA-BR-4184-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b76787ee-4ab4-472e-8a31-8f6addb9115e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4184-11A (Solid Tissue Normal), aliquot TCGA-BR-4184-11A-01D-1126-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/755ca174-3931-449a-883c-7ce6be259a38

The open-access MAF lists 3,677 somatic variants for this specimen: 2,721 protein-altering or splice-affecting, 886 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,107, Silent 886, Frame Shift Del 409, Nonsense Mutation 104, Frame Shift Ins 44, Intron 28, Splice Site 25, Splice Region 20, RNA 20, 3'UTR 11, In Frame Del 9, 3'Flank 6.

Variants (750 of 3,677; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1A | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1060505037, COSV56362133; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BBS10 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as rs1156913215, COSV53882168; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BIVM-ERCC5 | c.4113del p.K1371Nfs*65 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | catalogued as rs752661599, COSV100863757; ClinVar: pathogenic; called by mutect2, varscan2
- BRCA2 | c.1813del p.I605Yfs*9 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs80359306; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRCA2 | c.2957del p.N986Ifs*5 | Frame Shift Del (DEL) | VAF 12/116 reads (10%) | catalogued as rs80359365; ClinVar: pathogenic; called by mutect2, pindel
- CHRNA4 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs281865068, CM094469, COSV64719406; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CYP27B1 | c.171dup p.L58Afs*275 | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | catalogued as rs763437121; ClinVar: pathogenic; called by mutect2, varscan2
- DMD | c.9370_9371del p.L3124Efs*7 | Frame Shift Del (DEL) | VAF 18/33 reads (55%) | catalogued as rs1064793644; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 10/152 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2
- F8 | c.4379del p.N1460Ifs*5 | Frame Shift Del (DEL) | VAF 34/69 reads (49%) | catalogued as rs387906455, CD910498; ClinVar: pathogenic; called by mutect2, varscan2
- FAH | c.615del p.F205Lfs*2 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | catalogued as rs1057517084; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- GALC | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs746806459, COSV54325234; ClinVar: likely pathogenic; called by muse, varscan2
- HADHA | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as rs137852775, CM983469, COSV66106265; ClinVar: pathogenic; called by muse, mutect2, varscan2
- INPPL1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 27/69 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53353022, COSV99995692; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MTTP | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs199422220, CM961001, COSV55505714; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 6/12 reads (50%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NGF | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11466112, CM040787; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 29/104 reads (28%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PEX16 | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514472, CM105391, COSV99571130; ClinVar: pathogenic; called by mutect2, varscan2
- RTEL1 | c.1482-1G>A p.X494_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as rs863225129, CS150587, COSV58893789; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 24/109 reads (22%) | catalogued as rs794726736, CM096095, COSV57669359; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SERPINA1 | c.1158del p.E387Rfs*11 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | catalogued as rs764325655, CD890162; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SPART | c.696dup p.V233Cfs*8 | Frame Shift Ins (INS) | VAF 24/93 reads (26%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- SPG11 | c.3075del p.E1026Sfs*12 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | catalogued as rs312262752; ClinVar: pathogenic; called by mutect2, varscan2
- STXBP1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1064794322, COSV64813096; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMEM200C | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs374225402; called by mutect2, varscan2
- TP53 | c.733G>C p.G245R | Missense Mutation (SNP) | VAF 14/57 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, varscan2
- TRNT1 | c.1252del p.S418Vfs*11 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | catalogued as rs876661298, CM1411168, COSV51642664; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- A2M | c.3422G>A p.G1141D | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.33); catalogued as COSV59386313; called by muse, mutect2, varscan2
- A2ML1 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs770246364, COSV55288421; called by muse, mutect2, varscan2
- AAK1 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV68643671; called by muse, mutect2, varscan2
- ABCA10 | c.941del p.F314Sfs*11 | Frame Shift Del (DEL) | VAF 23/87 reads (26%) | catalogued as rs771346448; called by mutect2, pindel, varscan2
- ABCA10 | c.574T>C p.S192P | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs372720119; called by muse, mutect2, varscan2
- ABCA13 | c.1232G>A p.G411D | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs557664531, COSV70027942; called by muse, mutect2, varscan2
- ABCA13 | c.7408G>A p.A2470T | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs763339803, COSV71287479; called by muse, mutect2, varscan2
- ABCA13 | c.11152G>A p.A3718T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777083484, COSV71285284; called by muse, varscan2
- ABCA13 | c.12134C>T p.A4045V | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs752909768, COSV71287484; called by mutect2, varscan2
- ABCA5 | c.3779A>C p.D1260A | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV67016762; called by muse, mutect2, varscan2
- ABCA5 | c.742del p.I248* | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs751460805, COSV67017665; called by mutect2, varscan2
- ABCA6 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV52638423; called by muse, mutect2, varscan2
- ABCA8 | c.4622G>A p.S1541N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); catalogued as COSV52200797; called by muse, mutect2, varscan2
- ABCB10 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as rs143346649; called by muse, mutect2, varscan2
- ABCC10 | c.2107G>A p.A703T (on ENST00000372530 / NM_001198934.2; = p.A675T on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs140043327; called by muse, mutect2, varscan2
- ABCC10 | c.3439A>G p.T1147A (on ENST00000372530 / NM_001198934.2; = p.T1119A on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55087474; called by muse, mutect2, varscan2
- ABCC11 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs200134154; called by muse, mutect2, varscan2
- ABCC5 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs550542220, COSV55589847, COSV55597043; called by muse, mutect2, varscan2
- ABCD4 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150967109; called by muse, mutect2, varscan2
- ABCF2 | c.1527A>T p.Q509H | Missense Mutation (SNP) | VAF 76/308 reads (25%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.957); catalogued as COSV55182902; called by muse, mutect2, varscan2
- ABCF3 | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs776852066, COSV53052485; called by muse, mutect2, varscan2
- ABCG2 | c.829T>G p.F277V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52945839; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.039); catalogued as rs1193452940, COSV56472599; called by muse, mutect2, varscan2
- ABI3 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as rs769714351, COSV56799151; called by muse, mutect2, varscan2
- ABL1 | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 31/110 reads (28%) | catalogued as rs1371645607, COSV59326663; called by muse, mutect2, varscan2
- ABL2 | c.2264G>A p.R755H (on ENST00000502732 / NM_007314.4; = p.R740H on NM_005158.5) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.034); catalogued as rs147435995; called by muse, mutect2
- ABTB2 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1428655784, COSV54388033; called by mutect2, varscan2
- AC011462.1 | c.8G>A p.S3N | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV60531670; called by muse, mutect2, varscan2
- AC092143.1 | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.118); catalogued as COSV59247812; called by muse, mutect2, varscan2
- AC093827.5 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762808044, COSV55745188; called by muse, mutect2, varscan2
- ACAA2 | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 34/130 reads (26%) | catalogued as rs769900666, COSV53270389; called by muse, mutect2, varscan2
- ACACB | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV58134175; called by muse, mutect2, varscan2
- ACACB | c.2839C>T p.R947C | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373882930; called by muse, mutect2, varscan2
- ACADS | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs765604622, COSV54368877; called by muse, mutect2, varscan2
- ACAN | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs565318742, COSV61360056; called by muse, mutect2, varscan2
- ACAT1 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as rs747860630, COSV56187470; called by mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | catalogued as rs757016425; called by mutect2, varscan2
- ACCS | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.304); catalogued as rs1293425188, COSV55458198; called by muse, mutect2, varscan2
- ACHE | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as rs1343252087, COSV53817414; called by muse, mutect2, varscan2
- ACMSD | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as rs199569492, COSV51605508, COSV51606977; called by mutect2, varscan2
- ACOX3 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as rs116281866, COSV62710831; called by muse, mutect2, varscan2
- ACOX3 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768812405, COSV62711942; called by muse, mutect2, varscan2
- ACP1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55243172; called by muse, mutect2, varscan2
- ACP7 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV58699286; called by muse, mutect2, varscan2
- ACSBG1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as rs774511900, COSV51908268; called by muse, mutect2, varscan2
- ACSL4 | c.1991G>A p.R664Q (on ENST00000340800 / NM_022977.2; = p.R623Q on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs187046661, COSV61613941; called by muse, mutect2, varscan2
- ACSS3 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs772788931, COSV54083770; called by muse, mutect2, varscan2
- ACTB | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.254); catalogued as COSV59318056; called by muse, varscan2
- ACTG2 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.246); catalogued as COSV61828283; called by muse, mutect2, varscan2
- ACTR5 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780725473, COSV54760677, COSV54760819; called by mutect2, varscan2
- ACVR1B | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 36/169 reads (21%) | catalogued as COSV57774850; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 34/111 reads (31%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM28 | c.262_264del p.Y88del | In Frame Del (DEL) | VAF 18/70 reads (26%) | catalogued as rs1563275481; called by pindel, varscan2
- ADAM30 | c.2369del p.K790Sfs*36 | Frame Shift Del (DEL) | VAF 42/176 reads (24%) | catalogued as rs1557794075; called by mutect2, varscan2
- ADAMTS13 | c.3208G>A p.A1070T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.786); catalogued as rs782706998, COSV63021195; called by muse, mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 20/109 reads (18%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS5 | c.2624C>T p.S875L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs753190231, COSV53178906; called by muse, mutect2, varscan2
- ADAMTS9 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55780604; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as rs761956033, COSV52815302; called by mutect2, varscan2
- ADAMTSL1 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs554272440, COSV65891963; called by mutect2, varscan2
- ADAR | c.427A>T p.I143F | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV52715063; called by muse, mutect2, varscan2
- ADCK1 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs112630340, COSV53078037; called by muse, mutect2, varscan2
- ADCY1 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV52034283; called by muse, mutect2, varscan2
- ADCY1 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1290230631, COSV52034293; called by muse, mutect2, varscan2
- ADCY4 | c.2579G>A p.R860H | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as rs767502998, COSV60254120; called by muse, mutect2, varscan2
- ADGRB3 | c.152del p.N51Tfs*21 | Frame Shift Del (DEL) | VAF 15/116 reads (13%) | catalogued as COSV65411808; called by mutect2, pindel, varscan2
- ADGRB3 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs1245179033, COSV65417995; called by muse, varscan2
- ADGRB3 | c.1901G>T p.S634I | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.889); catalogued as COSV65394186; called by muse, mutect2, varscan2
- ADGRB3 | c.2134G>T p.A712S | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65394189; called by muse, mutect2, varscan2
- ADGRL1 | c.3158C>T p.A1053V (on ENST00000340736 / NM_001008701.3; = p.A1048V on NM_014921.5) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1568569440, COSV61564642; called by muse, mutect2, varscan2
- ADGRL3 | c.1000G>C p.A334P (on ENST00000506720 / NM_001322402.2; = p.A266P on NM_015236.6) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101546896; called by muse, mutect2
- ADH1C | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs769121542, COSV72463373; called by muse, mutect2, varscan2
- ADIPOR1 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV61851495; called by muse, varscan2
- ADRA1A | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs765619798, COSV52363407; called by muse, varscan2
- ADRA1A | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52363464; called by muse, varscan2
- ADRA1B | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs571519472, COSV60701056; called by muse, mutect2, varscan2
- ADRA1D | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as COSV65240747; called by muse, mutect2, varscan2
- AFAP1 | c.-1A>G | Splice Region (SNP) | VAF 30/96 reads (31%) | catalogued as COSV61795510; called by muse, mutect2, varscan2
- AFDN | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.389); catalogued as COSV60044080; called by muse, mutect2, varscan2
- AFDN | c.1939T>C p.S647P | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV60037813, COSV60044102; called by muse, mutect2, varscan2
- AFDN | c.4673G>A p.R1558H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60044148; called by muse, mutect2, varscan2
- AFP | c.1043del p.N348Ifs*22 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs779815391; called by mutect2, pindel, varscan2
- AGAP1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779782500, COSV58325426; called by muse, mutect2, varscan2
- AGBL1 | c.3050G>A p.G1017D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.007); catalogued as rs747719185, COSV66857627; called by mutect2, varscan2
- AGMO | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100693695; called by muse, mutect2, varscan2
- AGO1 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs1262161642, COSV64595240, COSV64596117; called by muse, mutect2, varscan2
- AGPAT4 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.373); catalogued as rs1158616160, COSV57245733; called by muse, mutect2
- AGTR2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs1556673661, COSV64156456; called by muse, mutect2, varscan2
- AHCTF1 | c.3414del p.F1138Lfs*16 (on ENST00000366508; = p.F1112Lfs*16 on NM_015446.5) | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs1476840751; called by mutect2, pindel, varscan2
- AHNAK | c.13067C>T p.A4356V | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV57204621; called by muse, mutect2
- AHNAK2 | c.15431G>A p.S5144N | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.047); catalogued as COSV60914894; called by muse, mutect2, varscan2
- AICDA | c.9-1G>A p.X3_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | catalogued as rs1185747879, COSV57564376; called by muse, mutect2
- AIG1 | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.801); catalogued as COSV51625876; called by muse, mutect2, varscan2
- AKAP11 | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV50296852; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP8 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs767746415, COSV54102409; called by mutect2, varscan2
- AKT2 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs572670425, COSV60908440; called by muse, mutect2, varscan2
- AL592490.1 | c.2003C>A p.A668D | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV69426186; called by muse, mutect2, varscan2
- ALCAM | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.049); catalogued as rs1403480123, COSV60248066; called by muse, mutect2, varscan2
- ALDH18A1 | c.2075G>A p.G692D | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64662547; called by muse, mutect2
- ALDH2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs1357957696, COSV55669971; called by muse, mutect2, varscan2
- ALG10 | c.904del p.S302Pfs*17 | Frame Shift Del (DEL) | VAF 44/174 reads (25%) | catalogued as rs779782051; called by mutect2, varscan2
- ALG10B | c.886del p.S296Hfs*23 | Frame Shift Del (DEL) | VAF 40/152 reads (26%) | catalogued as rs1397842268; called by mutect2, varscan2
- ALPG | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs542023570, COSV54964900; called by mutect2, varscan2
- ALPK2 | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV64492916; called by muse, mutect2, varscan2
- ALX3 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776967754, COSV63928742; called by muse, mutect2, varscan2
- AMBRA1 | c.3670C>T p.R1224* (on ENST00000458649 / NM_001367468.1; = p.R1134* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as rs1023861260, COSV54053486; called by muse, mutect2, varscan2
- AMOTL1 | c.2398G>A p.A800T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.369); catalogued as COSV58566476; called by muse, mutect2, varscan2
- AMPD2 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as rs376516473; called by muse, mutect2, varscan2
- AMPD3 | c.2218G>A p.A740T (on ENST00000396553 / NM_001025389.2; = p.A749T on NM_000480.3) | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV67330487; called by muse, mutect2, varscan2
- AMT | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1171313412, COSV99864409; called by muse, mutect2, varscan2
- AMZ1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs376501926; called by mutect2, varscan2
- ANGPT1 | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.098); catalogued as rs1260873818, COSV52439414; called by muse, mutect2, varscan2
- ANGPT1 | c.1190A>G p.E397G | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52439429; called by muse, mutect2
- ANGPT2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs749213090, COSV57334978; called by mutect2, varscan2
- ANGPTL6 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs780477052, COSV53462159; called by mutect2, varscan2
- ANK1 | c.2885C>T p.P962L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs140978700; called by mutect2, varscan2
- ANK2 | c.8920G>A p.A2974T | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100003899, COSV52160174; called by muse, mutect2
- ANK2 | c.9180A>C p.K3060N | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV52160183; called by muse, mutect2, varscan2
- ANK3 | c.3800C>T p.T1267M (on ENST00000280772 / NM_001320874.2; = p.T401M on NM_001149.3) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs753652746, COSV55056939; called by mutect2, varscan2
- ANKEF1 | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV65692412, COSV99058692; called by muse, mutect2, varscan2
- ANKRD11 | c.4055A>G p.H1352R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56360551; called by mutect2, varscan2
- ANKRD17 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226793492, COSV58217456; called by muse, mutect2, varscan2
- ANKRD36 | c.410A>G p.Y137C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101347228; called by muse, mutect2, varscan2
- ANKRD42 | c.684del p.D229Tfs*2 | Frame Shift Del (DEL) | VAF 15/75 reads (20%) | catalogued as rs1244878131; called by mutect2, pindel, varscan2
- ANKS1A | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64460547; called by muse, mutect2, varscan2
- ANO8 | c.350+2C>T p.X117_splice | Splice Site (SNP) | VAF 16/62 reads (26%) | catalogued as COSV50176846; called by muse, varscan2
- ANO8 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as rs751022259, COSV50176904; called by muse, varscan2
- ANXA13 | c.451del p.I151Sfs*20 | Frame Shift Del (DEL) | VAF 38/169 reads (22%) | catalogued as rs759218332; called by mutect2, varscan2
- ANXA6 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs374143469; called by muse, mutect2, varscan2
- AP3D1 | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.823); catalogued as COSV61428119; called by muse, mutect2, varscan2
- APBA2 | c.1616G>A p.S539N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs1336820274, COSV67104705; called by muse, mutect2, varscan2
- APC | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs762117133, COSV57340912; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APLP1 | c.698del p.P233Rfs*5 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as rs1407940597; called by mutect2, pindel
- APOBEC3G | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68470263; called by muse, mutect2, varscan2
- APPL1 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs551759110, COSV55700155; called by mutect2, varscan2
- AQP6 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1183142191, COSV59646290; called by muse, mutect2, varscan2
- ARAP1 | c.1495G>A p.D499N (on ENST00000393609 / NM_001040118.2; = p.D254N on NM_015242.4) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1480325852, COSV61991030; called by muse, varscan2
- ARAP2 | c.4439A>G p.D1480G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV58286505; called by muse, mutect2, varscan2
- ARFGAP2 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 51/199 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs1320658113, COSV53565624; called by muse, mutect2, varscan2
- ARFGEF1 | c.2526+2T>C p.X842_splice | Splice Site (SNP) | VAF 23/149 reads (15%) | catalogued as COSV51608071; called by muse, mutect2, varscan2
- ARFGEF2 | c.4739A>G p.H1580R | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV64212188; called by muse, mutect2, varscan2
- ARHGAP20 | c.1958G>A p.R653Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs759906371, COSV52810788; called by muse, mutect2, varscan2
- ARHGAP30 | c.3210del p.R1071Efs*33 (on ENST00000368013 / NM_001025598.2; = p.R860Efs*33 on NM_181720.3) | Frame Shift Del (DEL) | VAF 9/79 reads (11%) | catalogued as COSV63515260; called by mutect2, pindel, varscan2
- ARHGAP30 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 79/262 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs911473430, COSV63516348; called by muse, mutect2, varscan2
- ARHGAP32 | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749821981, COSV59847458; called by muse, mutect2, varscan2
- ARHGAP39 | c.2296G>A p.V766M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764235807, COSV52769859; called by mutect2, varscan2
- ARHGEF1 | c.2309G>A p.R770H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs781883859, COSV61527673; called by muse, mutect2, varscan2
- ARHGEF10 | c.754+2T>C p.X252_splice (on ENST00000398564; = p.X227_splice on NM_014629.4) | Splice Site (SNP) | VAF 12/81 reads (15%) | catalogued as COSV50649054; called by muse, mutect2, varscan2
- ARHGEF12 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs189894068, COSV63103147; called by muse, mutect2, varscan2
- ARHGEF17 | c.4172G>A p.S1391N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV55232366; called by muse, mutect2, varscan2
- ARHGEF25 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs542655828, COSV54089457; called by muse, mutect2, varscan2
- ARHGEF26 | c.716G>A p.S239N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100726399; called by muse, mutect2, varscan2
- ARHGEF26 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774329182, COSV100726400; called by muse, mutect2, varscan2
- ARID1A | c.4646G>T p.G1549V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.795); catalogued as COSV100250485, COSV61393336; called by muse, mutect2, varscan2
- ARID1A | c.5497C>T p.R1833C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs372213935; called by muse, mutect2, varscan2
- ARID1B | c.2960C>T p.A987V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.06); catalogued as rs750810656, COSV51652326; called by muse, mutect2, varscan2
- ARL11 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); catalogued as rs994780789, COSV56290713; called by muse, mutect2, varscan2
- ARL4A | c.548A>G p.H183R | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); catalogued as rs1457377816, COSV63319287; called by muse, mutect2, varscan2
- ARMC12 | c.790G>A p.A264T (on ENST00000373866 / NM_001286574.2; = p.A291T on NM_145028.5) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs200490512; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | catalogued as rs753865255; called by mutect2, varscan2
- ASAP1 | c.2639C>T p.S880L | Missense Mutation (SNP) | VAF 71/328 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV63048297; called by muse, mutect2, varscan2
- ASB2 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60111740; called by muse, mutect2
- ASB5 | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56670485; called by muse, mutect2, varscan2
- ASCC3 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as rs780854067, COSV61228296; called by mutect2, varscan2
- ASS1 | c.374A>G p.Q125R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61689317; called by mutect2, varscan2
- ASTN1 | c.3730C>T p.R1244W | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as rs747846402, COSV62496573; called by muse, mutect2, varscan2
- ASTN2 | c.947G>A p.S316N | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs754033577, COSV57775789; called by muse, mutect2, varscan2
- ATAD2B | c.2366A>G p.H789R | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV53198328; called by muse, varscan2
- ATAD2B | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53198340; called by muse, varscan2
- ATF7IP | c.30dup p.V11Sfs*3 | Frame Shift Ins (INS) | VAF 17/74 reads (23%) | catalogued as rs1161069252; called by mutect2, pindel, varscan2
- ATG16L1 | c.1745C>T p.A582V (on ENST00000392017 / NM_030803.7; = p.A563V on NM_017974.4) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs1471623952, COSV61465548, COSV61465600; called by muse, mutect2, varscan2
- ATG4D | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs754734757, COSV57264482; called by mutect2, varscan2
- ATP13A2 | c.2635G>A p.G879S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs771014262, COSV58700403, COSV58701431; called by muse, mutect2, varscan2
- ATP13A3 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV55464418; called by muse, mutect2, varscan2
- ATP13A4 | c.2011G>A p.A671T | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs372189734; called by muse, mutect2, varscan2
- ATP1A4 | c.2840G>A p.R947H | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs765825563, COSV63626434; called by muse, mutect2, varscan2
- ATP1B4 | c.478G>A p.A160T (on ENST00000218008 / NM_001142447.3; = p.A156T on NM_012069.5) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.081); catalogued as rs781753966, COSV54311680; called by mutect2, varscan2
- ATP2B1 | c.3304C>T p.R1102C | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV53806213, COSV99665778; called by muse, mutect2, varscan2
- ATP2B1 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.041); catalogued as rs759945140, COSV99665251; called by muse, mutect2, varscan2
- ATP2C1 | c.2291G>A p.R764H | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358466833, COSV60756111; called by muse, mutect2, varscan2
- ATP6V1H | c.1403G>A p.G468D | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as rs1218997778, COSV100778832, COSV62218223; called by muse, mutect2, varscan2
- ATP7A | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.336); catalogued as rs539177302, COSV58446048; ClinVar: uncertain significance; called by muse, mutect2
- ATP9B | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56950876; called by muse, mutect2, varscan2
- ATRN | c.939G>A p.W313* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as rs1215760424, COSV53527595; called by muse, mutect2
- ATRN | c.3786G>A p.W1262* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV53527603; called by muse, mutect2, varscan2
- ATRNL1 | c.2958G>A p.M986I | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1431292112, COSV58087188; called by muse, mutect2, varscan2
- AUH | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769894315, CM030784, COSV57862228; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AUTS2 | c.3131G>A p.R1044H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776489400, COSV61384447; called by muse, mutect2, varscan2
- AVP | c.100T>G p.S34A | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV66671858; called by muse, mutect2
- AVPR1A | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54546479; called by muse, mutect2, varscan2
- AVPR1A | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.144); catalogued as rs1347240517, COSV100146870, COSV54546488; called by muse, mutect2, varscan2
- AXIN1 | c.2410G>A p.A804T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.36); catalogued as rs764818271, COSV51987058; called by muse, mutect2, varscan2
- B3GALT2 | c.1130G>A p.S377N | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.042); catalogued as COSV66464031; called by muse, mutect2, varscan2
- B3GALT2 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66463723; called by muse, mutect2, varscan2
- B4GALNT3 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770313678, COSV56752228, COSV56758290; called by muse, mutect2, varscan2
- B4GALT2 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.107); catalogued as rs1160452876, COSV52543421; called by muse, mutect2, varscan2
- BACH2 | c.1286G>T p.R429M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV57591700; called by muse, mutect2, varscan2
- BAIAP3 | c.1862+1G>A p.X621_splice | Splice Site (SNP) | VAF 17/76 reads (22%) | catalogued as COSV50103961; called by muse, varscan2
- BATF2 | c.17del p.G6Afs*5 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as rs1471690036; called by mutect2, pindel, varscan2
- BAZ1A | c.3277C>T p.R1093W | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62410159; called by muse, mutect2
- BAZ1B | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59990981; called by muse, mutect2, varscan2
- BAZ2A | c.5660G>A p.R1887H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV51636449; called by muse, mutect2, varscan2
- BAZ2B | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 9/152 reads (6%) | catalogued as COSV58600381; called by muse, mutect2
- BCAM | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs773224737, COSV54302188; called by muse, mutect2
- BCAS4 | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52811330; called by muse, mutect2, varscan2
- BCKDHA | c.109-1G>A p.X37_splice | Splice Site (SNP) | VAF 14/39 reads (36%) | catalogued as COSV54197034; called by muse, mutect2, varscan2
- BCL6B | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs1200044113, COSV53427749; called by muse, varscan2
- BCOR | c.4850del p.L1617* (on ENST00000378444 / NM_001123385.2; = p.L1583* on NM_017745.6) | Frame Shift Del (DEL) | VAF 16/27 reads (59%) | catalogued as COSV60714399; called by mutect2, varscan2
- BCOR | c.1894G>A p.G632S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.453); catalogued as rs762605753, COSV100653958, COSV60706701; called by muse, mutect2, varscan2
- BDKRB2 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV60014782; called by mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs752427670; called by mutect2, varscan2
- BEND6 | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.01); catalogued as COSV66068896; called by muse, mutect2, varscan2
- BEST3 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766338045, COSV56993729, COSV56995604; called by muse, mutect2, varscan2
- BICD2 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs753729502, COSV63548847, COSV63548941; called by muse, mutect2, varscan2
- BIRC6 | c.4714T>C p.S1572P | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV70199039; called by muse, mutect2, varscan2
- BIRC6 | c.11801G>A p.R3934H | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs766431375, COSV70198526; called by muse, mutect2, varscan2
- BIRC6 | c.12233G>A p.G4078D | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66042823; called by muse, mutect2, varscan2
- BMP1 | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs775940520, COSV60479216; ClinVar: uncertain significance; called by mutect2, varscan2
- BMP15 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781989221, COSV53140438; called by mutect2, varscan2
- BMP2K | c.1253G>A p.G418D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.381); catalogued as rs142887199, COSV58595071; called by mutect2, varscan2
- BMP5 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs534656598, COSV63703078; called by muse, varscan2
- BNC2 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.401); catalogued as rs752429719, COSV66142952; called by muse, mutect2, varscan2
- BOC | c.3251C>T p.P1084L | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV56350566; called by muse, mutect2
- BOD1L1 | c.5258G>A p.R1753H | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs112328769, COSV99238510; called by muse, mutect2, varscan2
- BORA | c.1652G>A p.C551Y (on ENST00000613797; = p.C476Y on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV100909645; called by muse, mutect2, varscan2
- BPIFB3 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 61/367 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as rs766380597, COSV64956947; called by muse, mutect2, varscan2
- BPTF | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs773171191, COSV58836892; called by muse, mutect2, varscan2
- BPTF | c.4856C>T p.A1619V | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV58836906; called by muse, mutect2, varscan2
- BRCA2 | c.4315G>A p.A1439T | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs80358666, COSV66453413; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- BRCA2 | c.8852C>T p.A2951V | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66453430; called by muse, mutect2, varscan2
- BRD2 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV66373242; called by muse, mutect2, varscan2
- BRD7 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.306); catalogued as rs1457077883, COSV67158774; called by muse, mutect2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 8/36 reads (22%) | catalogued as rs749043197; called by mutect2, varscan2
- BRF1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759137877, COSV59268720; called by muse, mutect2, varscan2
- BRPF3 | c.2561del p.P854Rfs*6 | Frame Shift Del (DEL) | VAF 20/99 reads (20%) | catalogued as rs1413008697, COSV60208966; called by mutect2, pindel, varscan2
- BSN | c.10436C>T p.A3479V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs201323732; called by mutect2, varscan2
- BSPRY | c.647A>G p.Q216R | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as COSV65242679; called by muse, mutect2, varscan2
- BTAF1 | c.1569G>A p.W523* | Nonsense Mutation (SNP) | VAF 24/111 reads (22%) | catalogued as COSV56433780; called by muse, mutect2, varscan2
- BTBD1 | c.1049G>C p.R350P | Missense Mutation (SNP) | VAF 163/486 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55602936; called by muse, mutect2, varscan2
- BTN2A2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs780217318, COSV61856569; called by muse, mutect2, varscan2
- BTN3A3 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as rs200026955, COSV55071803; called by muse, mutect2, varscan2
- BTNL3 | c.1200del p.S401Afs*7 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | catalogued as rs757227190; called by mutect2, pindel, varscan2
- BTRC | c.1168C>T p.R390C (on ENST00000370187 / NM_033637.4; = p.R354C on NM_003939.5) | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1390897262, COSV64579481; called by muse, mutect2, varscan2
- C11orf24 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs571814219, COSV58504958; called by mutect2, varscan2
- C12orf42 | c.627T>A p.N209K | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV59382539; called by muse, mutect2, varscan2
- C12orf60 | c.236A>G p.D79G | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as COSV57451856; called by muse, mutect2, varscan2
- C15orf39 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62296627; called by muse, mutect2
- C16orf70 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 48/208 reads (23%) | catalogued as rs759485004, COSV54626322; called by muse, mutect2, varscan2
- C17orf97 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.385); catalogued as rs781884325, COSV64076469; called by muse, varscan2
- C17orf97 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs141704289; called by muse, varscan2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, pindel, varscan2
- C3 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as rs149692538; called by muse, mutect2, varscan2
- C5 | c.2405T>G p.V802G | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV56327008; called by muse, mutect2, varscan2
- C5AR1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.642); catalogued as rs1198210885, COSV61892573; called by mutect2, varscan2
- C5orf22 | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57598367; called by muse, mutect2, varscan2
- C6orf118 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.246); catalogued as COSV57814827; called by mutect2, varscan2
- C6orf58 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV61666470; called by muse, mutect2, varscan2
- C6orf62 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV65290459; called by muse, mutect2, varscan2
- C9orf131 | c.2707C>A p.P903T | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100398083, COSV56611074; called by muse, mutect2
- CAAP1 | c.571del p.I191Ffs*2 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as rs754356646, COSV61700397; called by mutect2, varscan2
- CABIN1 | c.5804G>A p.R1935Q | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as rs376189661; called by muse, mutect2, varscan2
- CABP7 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53363076; called by muse, mutect2, varscan2
- CACNA1D | c.2980G>A p.A994T (on ENST00000350061 / NM_001128840.3; = p.A1014T on NM_000720.4) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV55446390; called by muse, mutect2
- CACNA1E | c.3544C>T p.R1182C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs759093976, COSV62383640; called by mutect2, varscan2
- CACNA1E | c.4745G>A p.R1582H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62393577; called by muse, mutect2, varscan2
- CACNA1I | c.2642G>A p.S881N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV60807762; called by muse, varscan2
- CACNA1S | c.3686G>A p.R1229H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs774416016, COSV62939289; called by muse, mutect2, varscan2
- CACNB2 | c.989G>A p.R330H (on ENST00000324631 / NM_201596.3; = p.R275H on NM_000724.4) | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56622834; called by muse, mutect2, varscan2
- CACTIN | c.192G>A p.W64* | Nonsense Mutation (SNP) | VAF 11/59 reads (19%) | catalogued as rs1448334853, COSV50268004, COSV50268520; called by muse, mutect2, varscan2
- CACYBP | c.432del p.V145Sfs*22 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | catalogued as rs1161545619; called by mutect2, varscan2
- CADPS2 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs1563880632, COSV57362452; called by muse, mutect2, varscan2
- CALD1 | c.1682C>T p.A561V (on ENST00000361675 / NM_033138.4; = p.A306V on NM_004342.7) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs769729218, COSV62645782; called by mutect2, varscan2
- CALHM2 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs778156770, COSV53295670; called by mutect2, varscan2
- CAMK1D | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs762894154; called by muse, mutect2, varscan2
- CAMK2A | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1185191650, COSV62246329; called by muse, mutect2, varscan2
- CAMKK1 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV50116561; called by muse, mutect2, varscan2
- CAMSAP1 | c.2113G>C p.G705R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as COSV56722316; called by muse, mutect2, varscan2
- CAMSAP2 | c.3789del p.K1263Nfs*19 (on ENST00000236925 / NM_001297707.2; = p.K1252Nfs*19 on NM_203459.3) | Frame Shift Del (DEL) | VAF 27/122 reads (22%) | catalogued as rs770273913; called by mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 21/100 reads (21%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMTA1 | c.605A>C p.D202A | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57899347; called by muse, mutect2, varscan2
- CAND1 | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as rs371351780; called by muse, mutect2, varscan2
- CANX | c.1305del p.F435Lfs*12 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | catalogued as rs760711956; called by mutect2, varscan2
- CAP2 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs141863829, COSV57729659; called by mutect2, varscan2
- CAPN2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs763583591, COSV54336077; called by muse, mutect2, varscan2
- CAPN7 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as rs368130672; called by muse, mutect2, varscan2
- CAPN9 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); catalogued as rs759944848, COSV55233430; called by muse, mutect2, varscan2
- CAPNS1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1424161891, COSV55822770; called by muse, mutect2, varscan2
- CAPS2 | c.1624A>G p.I542V | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as rs1384115842, COSV60825411; called by muse, mutect2, varscan2
- CAPZA1 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs764250947, COSV54145279; called by mutect2, varscan2
- CARD11 | c.1814G>A p.S605N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV62755216; called by muse, mutect2
- CARTPT | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV57114988; called by muse, mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | catalogued as rs765105588; called by mutect2, varscan2
- CASP8AP2 | c.665G>A p.C222Y | Missense Mutation (SNP) | VAF 42/320 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV52746845, COSV99386701; called by muse, varscan2
- CASR | c.1837C>T p.L613F (on ENST00000490131; = p.L690F on NM_000388.4) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1467832380, COSV56137256; called by muse, mutect2, varscan2
- CASZ1 | c.3511G>A p.A1171T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs769502938, COSV59735301; called by mutect2, varscan2
- CATSPER2 | c.1366G>A p.E456K (on ENST00000321596 / NM_001282309.3; = p.E458K on NM_172095.4) | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.037); catalogued as COSV58660808; called by muse, mutect2, varscan2
- CATSPERB | c.2434G>A p.A812T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV56426206; called by muse, mutect2, varscan2
- CBFB | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1467426352, COSV51998270; called by muse, mutect2, varscan2
- CBLC | c.442A>C p.M148L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1190196751, COSV54322515; called by muse, mutect2, varscan2
- CBWD5 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as rs773139543, COSV101070705; called by mutect2, varscan2
- CCDC102B | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368864406; called by muse, mutect2, varscan2
- CCDC112 | c.378_379del p.K127Sfs*27 | Frame Shift Del (DEL) | VAF 36/160 reads (23%) | catalogued as rs1292871202; called by pindel, varscan2
- CCDC141 | c.2889del p.V964Lfs*10 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | catalogued as COSV55377999; called by mutect2, pindel, varscan2
- CCDC141 | c.2458G>A p.A820T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV55373209; called by muse, mutect2, varscan2
- CCDC171 | c.3580C>T p.P1194S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs1408277954, COSV99899949; called by muse, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 20/105 reads (19%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC39 | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs749477939, COSV56483761; called by muse, varscan2
- CCDC40 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs749446675, CD110046, COSV53896615; called by muse, mutect2, varscan2
- CCDC68 | c.79T>C p.S27P | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV61603628; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC92 | c.801del p.I268Sfs*40 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs773752200; called by mutect2, varscan2
- CCDC92 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.458); catalogued as rs775416812, COSV53019752; called by muse, mutect2, varscan2
- CCKBR | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as rs201033271, COSV58100101; called by muse, mutect2, varscan2
- CCN4 | c.793A>G p.T265A | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV51531554; called by muse, mutect2, varscan2
- CCNB1IP1 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62302755, COSV62303193; called by muse, mutect2, varscan2
- CCNYL1 | c.519+3_519+6del p.X173_splice (on ENST00000295414 / NM_001330218.2; = p.X103_splice on NM_152523.2) | Splice Site (DEL) | VAF 8/65 reads (12%) | catalogued as rs1396063963; called by mutect2, pindel, varscan2
- CCR5 | c.197A>G p.D66G | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52751577; called by muse, mutect2, varscan2
- CCT6A | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV51905537; called by muse, mutect2, varscan2
- CCT6B | c.1143G>T p.K381N | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV58489070; called by muse, mutect2, varscan2
- CD163L1 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs763534001, COSV58015762; called by muse, mutect2, varscan2
- CD1B | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as COSV63803735; called by muse, mutect2, varscan2
- CD1B | c.982T>A p.S328T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.614); catalogued as COSV63804277; called by muse, mutect2, varscan2
- CD247 | c.463G>A p.A155T (on ENST00000362089 / NM_198053.3; = p.A154T on NM_000734.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs561262982, COSV54816287; called by muse, mutect2, varscan2
- CD34 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1358058744, COSV60412874; called by muse, mutect2, varscan2
- CD5 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs759626085, COSV61718127, COSV61719234; called by mutect2, varscan2
- CD79A | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as rs374041941; called by mutect2, varscan2
- CD93 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs769815543, COSV55664313; called by muse, mutect2, varscan2
- CD93 | c.1307del p.G436Afs*152 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as rs779465056; called by mutect2, pindel, varscan2
- CDC23 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67509789; called by muse, mutect2, varscan2
- CDC25C | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776347990, COSV60399360; called by muse, mutect2, varscan2
- CDC42BPB | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs368416667; called by muse, mutect2, varscan2
- CDC5L | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65175756; called by muse, varscan2
- CDC5L | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1006568146, COSV65176002; called by muse, mutect2, varscan2
- CDC6 | c.1027T>C p.F343L | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52930460; called by muse, mutect2, varscan2
- CDC7 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs539320135, COSV52310602; called by muse, mutect2, varscan2
- CDH10 | c.1569A>T p.K523N | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs1268349921, COSV52580120; called by muse, mutect2, varscan2
- CDH10 | c.1394-1G>T p.X465_splice | Splice Site (SNP) | VAF 20/89 reads (22%) | catalogued as rs1258311939, COSV52580127; called by muse, mutect2, varscan2
- CDH10 | c.1367A>T p.N456I | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52580139; called by muse, mutect2, varscan2
- CDH10 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as rs1296415762, COSV52580147; called by muse, mutect2, varscan2
- CDH12 | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199892587, COSV66403949; called by mutect2, varscan2
- CDH20 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs536378751, COSV53009460; called by muse, varscan2
- CDH22 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV64837479; called by mutect2, varscan2
- CDH26 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.009); catalogued as COSV54846747; called by muse, mutect2, varscan2
- CDH3 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.044); catalogued as rs1567455480, COSV50557457; called by muse, mutect2, varscan2
- CDH9 | c.1838C>T p.T613M | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs768684659, COSV50281922; called by mutect2, varscan2
- CDK12 | c.3350C>T p.A1117V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV70999282, COSV71000594; called by muse, mutect2, varscan2
- CDK14 | c.1366A>G p.K456E (on ENST00000380050 / NM_001287135.2; = p.K438E on NM_012395.3) | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as COSV56034063; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs746203438, COSV62573211, COSV62573947; called by muse, mutect2, varscan2
- CDK5RAP2 | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV62574173; called by muse, mutect2, varscan2
- CDKAL1 | c.82C>T p.H28Y | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51183028; called by muse, mutect2, varscan2
- CDKL3 | c.1772del p.F591Sfs*9 | Frame Shift Del (DEL) | VAF 40/152 reads (26%) | catalogued as rs753494539; called by mutect2, varscan2
- CDKN2D | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs577358923, COSV57264484; called by muse, mutect2, varscan2
- CDON | c.2821A>G p.T941A | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54997684; called by muse, mutect2, varscan2
- CEACAM3 | c.658del p.L220Yfs*15 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs1555827517; called by mutect2, pindel, varscan2
- CEACAM6 | c.12del p.S5Qfs*21 | Frame Shift Del (DEL) | VAF 11/106 reads (10%) | catalogued as COSV52268704; called by mutect2, pindel, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 14/41 reads (34%) | catalogued as rs375852685; called by mutect2, varscan2
- CELF4 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV58452758; called by muse, mutect2, varscan2
- CELSR2 | c.6557G>A p.R2186H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs141644848; called by muse, mutect2, varscan2
- CEMIP | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as rs1196230359, COSV54992310; called by muse, mutect2, varscan2
- CEMIP | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778020593, COSV54992323; called by muse, mutect2, varscan2
- CENPC | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs371671240, COSV56623034; called by mutect2, varscan2
- CENPE | c.4232C>A p.P1411H | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV54380882; called by muse, mutect2, varscan2
- CENPJ | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs192296063, COSV67883414; called by muse, mutect2, varscan2
- CEP104 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764366578, COSV58215086; called by mutect2, varscan2
- CEP128 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as rs758957939, COSV99382884; called by muse, mutect2, varscan2
- CEP164 | c.1671G>T p.E557D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV54040987; called by muse, mutect2, varscan2
- CEP250 | c.5083C>T p.R1695* | Nonsense Mutation (SNP) | VAF 14/146 reads (10%) | catalogued as rs746831149, COSV61168070; called by mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 36/146 reads (25%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEP350 | c.4124G>A p.R1375H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs754615992, COSV62602128, COSV62605336; called by muse, mutect2, varscan2
- CEP43 | c.785A>G p.K262R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs768274661, COSV62760821; called by muse, mutect2, varscan2
- CEP57 | c.785del p.K262Rfs*31 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs762013265, COSV57689966; called by mutect2, varscan2
- CEP85L | c.2066G>A p.G689D | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100874084; called by muse, mutect2, varscan2
- CERS6 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs755919514, COSV59834601; called by muse, mutect2, varscan2
- CES1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs563293177, COSV100828653, COSV62086839; called by muse, mutect2, varscan2
- CES1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.85); catalogued as COSV62086303; called by muse, mutect2, varscan2
- CFAP206 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.408); catalogued as rs750840329, COSV51534041; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP251 | c.285A>C p.E95D | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV55839459; called by muse, mutect2
- CFAP251 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56610250; called by muse, mutect2, varscan2
- CFAP44 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV55611199; called by muse, mutect2, varscan2
- CFAP46 | c.7622C>T p.A2541V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.062); catalogued as rs143790683, COSV54155598; called by muse, mutect2, varscan2
- CFAP58 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as rs771146970, COSV57212069; called by muse, mutect2, varscan2
- CFAP65 | c.2134G>A p.A712T | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.481); catalogued as rs971967725, COSV58560735; called by muse, mutect2, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as rs778664468; called by pindel, varscan2
- CFAP65 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV55390262; called by muse, mutect2, varscan2
- CFAP91 | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV56340891; called by muse, mutect2, varscan2
- CGN | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs761721175, COSV54967727; called by muse, mutect2, varscan2
- CHAF1A | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); catalogued as rs769295287, COSV56672036; called by muse, mutect2, varscan2
- CHD1 | c.1528C>A p.L510I | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV52340020; called by muse, varscan2
- CHD1 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs778115031, COSV52340032; called by muse, mutect2, varscan2
- CHD1L | c.1834T>C p.S612P | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV63613868; called by muse, mutect2, varscan2
- CHD2 | c.3207G>A p.M1069I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV67708973; called by muse, mutect2, varscan2
- CHD2 | c.3830G>A p.G1277D | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67708985, COSV67715576; called by muse, mutect2, varscan2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 26/160 reads (16%) | catalogued as rs1322050057; called by mutect2, varscan2
- CHD6 | c.4657C>T p.L1553F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV64690552; called by muse, mutect2, varscan2
- CHD6 | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs369595632; called by muse, mutect2, varscan2
- CHD8 | c.3274C>T p.R1092C (on ENST00000646647 / NM_001170629.2; = p.R813C on NM_020920.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439223724, COSV67870139; called by muse, varscan2
- CHD9 | c.5665G>A p.A1889T | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as rs563054232, COSV54610046; called by mutect2, varscan2
- CHD9 | c.7922C>T p.A2641V (on ENST00000398510 / NM_001382353.1; = p.A2625V on NM_025134.7) | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV54610178; called by muse, mutect2, varscan2
- CHORDC1 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV57705983; called by muse, mutect2, varscan2
- CHRM4 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.099); catalogued as COSV63126499; called by muse, mutect2, varscan2
- CHRNB3 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51494964; called by muse, varscan2
- CHST15 | c.1271A>G p.Q424R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV60562015; called by muse, mutect2, varscan2
- CHST9 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1468731214, COSV52436777; called by muse, mutect2
- CIAO3 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV52402154; called by muse, mutect2, varscan2
- CILK1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs901020533, COSV63153887; called by muse, mutect2, varscan2
- CIT | c.5098C>T p.L1700F | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.69); catalogued as COSV55868115; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as rs752250702; called by mutect2, varscan2
- CKAP2L | c.1445C>A p.P482H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1037829641, COSV56696420; called by muse, mutect2, varscan2
- CKAP5 | c.2991+2T>C p.X997_splice | Splice Site (SNP) | VAF 6/62 reads (10%) | catalogued as COSV56367555; called by muse, mutect2
- CKMT2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs548849398, COSV54172310; called by muse, varscan2
- CLASP2 | c.3175C>T p.R1059W (on ENST00000359576; = p.R1058W on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56276496; called by muse, mutect2, varscan2
- CLASP2 | c.2896del p.M966Wfs*33 (on ENST00000359576; = p.M965Wfs*33 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 21/130 reads (16%) | catalogued as rs761731080; called by mutect2, varscan2
- CLCA2 | c.745-2A>G p.X249_splice | Splice Site (SNP) | VAF 24/68 reads (35%) | catalogued as COSV65287095; called by muse, mutect2, varscan2
- CLCN5 | c.2207C>T p.A736V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as rs782682661, COSV56586534; called by muse, mutect2, varscan2
- CLDN20 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65697209; called by muse, varscan2
- CLDN25 | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71620435; called by muse, mutect2, varscan2
- CLEC4F | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.056); catalogued as rs1302121141, COSV55478417; called by muse, mutect2, varscan2
- CLEC4M | c.930G>T p.E310D | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV50218766, COSV50222501; called by muse, mutect2, varscan2
- CLGN | c.1622del p.K541Sfs*27 | Frame Shift Del (DEL) | VAF 54/251 reads (22%) | catalogued as rs1364341002; called by mutect2, pindel, varscan2
- CLIC5 | c.586C>T p.R196C (on ENST00000185206 / NM_001370649.1; = p.R37C on NM_016929.5) | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs999896490, COSV51758493; called by muse, mutect2, varscan2
- CLIP1 | c.3646del p.R1216Efs*6 (on ENST00000620786 / NM_001247997.1; = p.R1205Efs*6 on NM_002956.2) | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | catalogued as rs761972338; called by mutect2, varscan2
- CLN6 | c.397_398del p.V133Qfs*17 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | catalogued as rs766493088; called by mutect2, varscan2
- CMTM2 | c.11A>C p.K4T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51748695; called by muse, mutect2, varscan2
- CNDP2 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as rs1315165964, COSV100158930; called by muse, mutect2, varscan2
- CNGA1 | c.1327del p.T443Qfs*8 | Frame Shift Del (DEL) | VAF 33/157 reads (21%) | catalogued as rs772867912; called by mutect2, pindel, varscan2
- CNGA4 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs746858122, COSV66005874; called by muse, mutect2, varscan2
- CNN1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs148076740; called by muse, mutect2, varscan2
- CNOT2 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV57502220; called by muse, mutect2
- CNOT6 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs763363186, COSV56159543; called by muse, mutect2, varscan2
- CNOT6L | c.917C>T p.A306V (on ENST00000504123 / NM_001286790.2; = p.A301V on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1481358623, COSV53698148; called by muse, mutect2, varscan2
- CNR1 | c.838A>T p.I280F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62987232; called by muse, varscan2
- CNTD1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV59311936; called by muse, mutect2, varscan2
- CNTN1 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs201782849, COSV61636026; called by mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP1 | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs760960237, COSV52850362; called by muse, mutect2, varscan2
- CNTNAP2 | c.1952T>C p.V651A | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV62177993; called by muse, mutect2, varscan2
- COBLL1 | c.3472C>T p.R1158* (on ENST00000392717; = p.R1120* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as rs868427833, COSV52067513; called by muse, mutect2, varscan2
- COBLL1 | c.3236G>A p.R1079H (on ENST00000392717; = p.R1041H on NM_014900.5) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs540904114, COSV52067533; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 16/25 reads (64%) | catalogued as rs374805044; called by mutect2, varscan2
- COL12A1 | c.6167G>T p.R2056M | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59395638; called by muse, mutect2, varscan2
- COL14A1 | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs901427317, COSV52849813, COSV52852703; called by muse, varscan2
- COL19A1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.642); catalogued as rs1178902584, COSV100505503, COSV59572208; called by muse, varscan2
- COL1A1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1435869455, COSV56804765; called by muse, varscan2
- COL1A2 | c.3568G>A p.A1190T | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs1040559526, COSV51957680, COSV99799279; called by muse, mutect2, varscan2
- COL22A1 | c.3012+2T>C p.X1004_splice | Splice Site (SNP) | VAF 34/178 reads (19%) | catalogued as rs1358076153, COSV57335900; called by muse, varscan2
- COL22A1 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV57335912; called by muse, mutect2, varscan2
- COL25A1 | c.708+1G>A p.X236_splice | Splice Site (SNP) | VAF 21/92 reads (23%) | catalogued as rs1363544967, COSV67649901; called by muse, mutect2, varscan2
- COL27A1 | c.5209G>A p.A1737T | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.908); catalogued as COSV61925834; called by muse, mutect2, varscan2
- COL4A1 | c.3095G>A p.G1032D | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65425340; called by muse, mutect2, varscan2
- COL4A1 | c.1657G>A p.G553S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370670458; called by muse, mutect2, varscan2
- COL4A1 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.09); catalogued as rs779300770, COSV65423479; called by mutect2, varscan2
- COL4A2 | c.2554C>T p.P852S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); catalogued as rs1157780529, COSV64628077; called by muse, mutect2, varscan2
- COL4A6 | c.2219G>A p.S740N | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.102); catalogued as COSV57866108; called by muse, mutect2, varscan2
- COL6A2 | c.2038C>T p.R680C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764371488, COSV56004454; called by muse, mutect2, varscan2
- COL9A1 | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV61831974; called by muse, mutect2, varscan2
- COLGALT1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs747606083, COSV53108843; called by mutect2, varscan2
- COMMD3-BMI1 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100936313; called by muse, mutect2, varscan2
- COPA | c.3379C>T p.R1127C | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749061726, COSV54102132; called by muse, mutect2, varscan2
- COPG1 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV100135395; called by muse, mutect2, varscan2
- CPB1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs766816862, COSV51573302; called by mutect2, varscan2
- CPED1 | c.933del p.F311Lfs*5 | Frame Shift Del (DEL) | VAF 42/163 reads (26%) | catalogued as rs1361659782; called by mutect2, pindel, varscan2
- CPNE5 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs755076731, COSV55198199; called by muse, mutect2, varscan2
- CPXM1 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769586671, COSV101013685, COSV66045458; called by mutect2, varscan2
- CPXM2 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1453578509, COSV53856278; called by muse, mutect2, varscan2
- CRB2 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1474833179, COSV63503082; called by mutect2, varscan2
- CRB2 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs756607676, COSV63503090; called by muse, mutect2, varscan2
- CRB2 | c.2408C>T p.A803V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs932396631, COSV63503099; called by muse, mutect2
- CREB3 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs1038522290, COSV59207284; called by mutect2, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 30/96 reads (31%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CRIM1 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV54861718; called by muse, mutect2
- CRIM1 | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs755928305, COSV54863726; called by muse, mutect2, varscan2
- CRMP1 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs371310830; called by muse, mutect2, varscan2
- CROT | c.965G>A p.G322D | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV58974123; called by muse, mutect2, varscan2
- CSF1R | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.086); catalogued as COSV53834580; called by muse, mutect2, varscan2
- CSF1R | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as rs761316359, COSV53834600; called by muse, mutect2, varscan2
- CSF2RA | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV62624573; called by muse, mutect2
- CSGALNACT1 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as rs773946667, COSV59977255; called by muse, mutect2
- CSH1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs139446025; called by muse, mutect2, varscan2
- CSMD2 | c.10388A>G p.D3463G | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV53910277; called by muse, mutect2, varscan2
- CSMD2 | c.3973G>A p.V1325M | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as rs142169949, COSV53884491; called by muse, mutect2, varscan2
- CSMD3 | c.9346A>T p.N3116Y (on ENST00000297405 / NM_001363185.1; = p.N2947Y on NM_052900.3) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52174593; called by muse, mutect2, varscan2
- CSMD3 | c.1352C>T p.A451V (on ENST00000297405 / NM_001363185.1; = p.A347V on NM_052900.3) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as rs1168189799, COSV52154510, COSV52174611; called by muse, mutect2, varscan2
- CSPG4 | c.6767A>G p.D2256G | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV57894749; called by mutect2, varscan2
- CSPG5 | c.1553C>A p.A518D (on ENST00000383738 / NM_001206943.2; = p.A491D on NM_006574.4) | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV53131224; called by muse, varscan2
- CSRNP1 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs757630647, COSV56188038; called by muse, mutect2, varscan2
- CSTB | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV52366835; called by muse, mutect2, varscan2
- CSTF3 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as rs1213854449, COSV60611172; called by muse, mutect2, varscan2
- CTDP1 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs781594932, COSV50003119; called by muse, mutect2, varscan2
- CTRL | c.293C>A p.P98H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV52123319; called by muse, mutect2, varscan2
- CTSH | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs201782561, COSV54985005; called by mutect2, varscan2
- CTTNBP2 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs201464133; called by mutect2, varscan2
- CUBN | c.6257C>T p.A2086V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV64715202; called by muse, mutect2, varscan2
- CUL2 | c.1547C>A p.A516E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66078403, COSV66079131; called by muse, mutect2, varscan2
- CUL5 | c.300C>A p.F100L | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV67608842; called by muse, mutect2, varscan2
- CUTA | c.224G>A p.C75Y (on ENST00000488034 / NM_001014840.2; = p.C52Y on NM_015921.3) | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53381165; called by muse, mutect2, varscan2
- CUX1 | c.61G>A p.A21T (on ENST00000292535 / NM_181552.4; = p.A32T on NM_001913.5) | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52898658; called by muse, mutect2, varscan2
- CUX1 | c.1427C>T p.A476V (on ENST00000437600 / NM_181500.4; = p.A478V on NM_001913.5) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs1554547099, COSV52930514; called by muse, mutect2, varscan2
- CWC22 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs761676860, COSV55426364, COSV55433719; called by muse, mutect2, varscan2
- CYBB | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1307931082, COSV66085342; called by muse, mutect2, varscan2
- CYGB | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs781254798, COSV53150184; called by mutect2, varscan2
- CYP2C18 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1164005268, COSV53672116; called by muse, mutect2, varscan2
- CYP2C18 | c.1329G>T p.M443I | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV53670384, COSV53671143, COSV53672129; called by muse, mutect2, varscan2
- CYP2C19 | c.1010C>A p.P337H | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758787238, COSV64907692; called by muse, mutect2, varscan2
- CYP2J2 | c.698T>C p.F233S | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV64606105; called by muse, mutect2
- CYP4F12 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200041881, COSV61173156; called by mutect2, varscan2
- CYP4V2 | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV66505743; called by muse, mutect2, varscan2
- DAB2 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV57914266; called by muse, mutect2, varscan2
- DAB2IP | c.805C>T p.R269C (on ENST00000408936; = p.R241C on NM_032552.3) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs759742711, COSV52258888; called by muse, mutect2, varscan2
- DAB2IP | c.1556C>T p.A519V (on ENST00000408936; = p.A491V on NM_032552.3) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52258905; called by muse, mutect2, varscan2
- DAXX | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as rs765273333, COSV56468534, COSV56469183; called by muse, varscan2
- DAZAP2 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 75/300 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as rs144235964, COSV66312995; called by muse, mutect2, varscan2
- DBF4 | c.964A>G p.N322D | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.215); catalogued as COSV55996768; called by muse, mutect2, varscan2
- DCAF1 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.467); catalogued as rs983271767, COSV60042763; called by muse, mutect2, varscan2
- DCAF4L1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs1453874781, COSV60787183, COSV60788339; called by muse, mutect2, varscan2
- DCAF5 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1486198582, COSV58460255; called by muse, mutect2, varscan2
- DCANP1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs373679643, COSV72345812; called by muse, mutect2, varscan2
- DCC | c.2726G>A p.G909D | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.124); catalogued as COSV59101289; called by muse, mutect2, varscan2
- DCHS1 | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.59); catalogued as rs1205130469, COSV55034465; called by muse, mutect2, varscan2
- DCST1 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as rs1308352706, COSV55059192; called by muse, mutect2, varscan2
- DCTN1 | c.2754del p.S919Afs*25 | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | catalogued as rs1229620804; called by mutect2, pindel, varscan2
- DCUN1D4 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755838496, COSV58122689; called by mutect2, varscan2
- DDAH2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs760623483, COSV65383782, COSV65383927; called by muse, mutect2, varscan2
- DDC | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs781573378, COSV63565129; called by muse, mutect2, varscan2
- DDHD1 | c.1303C>T p.R435C (on ENST00000323669; = p.R632C on NM_030637.3) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs372260629; called by muse, mutect2, varscan2
- DDX10 | c.238del p.T80Hfs*2 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs1176416201; called by mutect2, pindel, varscan2
- DDX18 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1239252736, COSV54306620; called by muse, mutect2, varscan2
- DDX24 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1460975526, COSV58212430; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 44/155 reads (28%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX42 | c.2759C>T p.A920V | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.051); catalogued as COSV63790082; called by muse, mutect2, varscan2
- DDX49 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV53230448; called by muse, mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs778036194; called by mutect2, varscan2
- DEDD | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs764036709, COSV63501623; called by mutect2, varscan2
- DEFB118 | c.78del p.K26Nfs*19 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as rs750510475, COSV53620107; called by mutect2, varscan2
- DENND4C | c.3836G>A p.R1279H (on ENST00000434457 / NM_001330640.2; = p.R1230H on NM_017925.7) | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1046400679, COSV63008762; called by muse, mutect2, varscan2
- DGKA | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs373733309; called by muse, mutect2, varscan2
- DGKB | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs765803079, COSV51781139; called by muse, mutect2, varscan2
- DGKH | c.583_584del p.L196Ffs*14 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | catalogued as rs1345516910; called by pindel, varscan2
- DGKH | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.157); catalogued as COSV54931794; called by muse, mutect2
- DGKI | c.2749del p.R917Afs*18 | Frame Shift Del (DEL) | VAF 19/94 reads (20%) | catalogued as COSV55936701; called by mutect2, pindel, varscan2
- DHCR7 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs767031102, COSV100831779, COSV62795146, COSV62796610; called by muse, mutect2, varscan2
- DHDH | c.542G>A p.C181Y | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs746802676, COSV55482108; called by muse, mutect2, varscan2
- DHTKD1 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.43); catalogued as rs1489239885, COSV53803445; called by muse, mutect2, varscan2
- DHX16 | c.2207G>A p.R736H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs777560628, COSV53313056, COSV53313904; called by mutect2, varscan2
- DHX30 | c.1793G>A p.R598H (on ENST00000445061 / NM_138615.3; = p.R559H on NM_014966.3) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs1372001045, COSV53137515; called by mutect2, varscan2
- DHX34 | c.3253G>A p.A1085T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1227575421, COSV60895355; called by muse, mutect2, varscan2
- DHX35 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759598323, COSV52670046; called by muse, mutect2, varscan2
- DHX36 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs1459672619, COSV57672617; called by muse, mutect2, varscan2
- DHX37 | c.2033G>A p.G678D | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1321923614, COSV58134343; called by muse, mutect2
- DHX38 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs747622765, COSV51697841; called by mutect2, varscan2
- DHX38 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV51697854; called by muse, mutect2, varscan2
- DIP2A | c.3498G>T p.K1166N | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.821); catalogued as COSV59477190; called by muse, mutect2, varscan2
- DIP2A | c.3826C>T p.R1276C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs760071686, COSV59477212; called by mutect2, varscan2
- DIP2A | c.4342C>T p.R1448W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs759320654, COSV59476549; called by muse, mutect2, varscan2
- DIP2C | c.1843C>T p.R615* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as rs1419537231, COSV55157254; called by muse, mutect2, varscan2
- DIS3L2 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1017419118, COSV56053987; called by muse, mutect2, varscan2
- DISP3 | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1484964650, COSV53826790; called by muse, mutect2, varscan2
- DISP3 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1186903277, COSV53819377; called by muse, mutect2, varscan2
- DISP3 | c.3854C>T p.A1285V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1454574153, COSV53826834; called by muse, varscan2
- DLEC1 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV57299408; called by muse, mutect2, varscan2
- DLGAP2 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV70097885; called by mutect2, varscan2
- DLL1 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as rs780734657, COSV64537468; called by muse, mutect2, varscan2
- DLX2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1383128488, COSV52232091; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAAF4 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV58248790; called by muse, mutect2, varscan2
- DNAAF5 | c.1303G>A p.V435M | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52416607; called by muse, mutect2, varscan2
- DNAAF5 | c.2513C>T p.A838V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs1267376926, COSV52416628; called by muse, mutect2, varscan2
- DNAH10 | c.6215C>T p.S2072L (on ENST00000409039; = p.S2011L on NM_207437.3) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs774732784, COSV68993361; called by muse, varscan2
- DNAH2 | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs755023427, COSV50014450; called by muse, mutect2, varscan2
- DNAH2 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.021); catalogued as COSV66719292; called by muse, mutect2, varscan2
- DNAH3 | c.5761T>C p.Y1921H | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV54520366; called by muse, mutect2, varscan2
- DNAH3 | c.3330del p.R1111Gfs*18 | Frame Shift Del (DEL) | VAF 25/128 reads (20%) | catalogued as COSV99764126; called by mutect2, pindel, varscan2
- DNAH8 | c.2617C>T p.R873* | Nonsense Mutation (SNP) | VAF 25/158 reads (16%) | catalogued as rs199969537, COSV59441157; called by muse, mutect2, varscan2
- DNAH8 | c.4418del p.N1473Ifs*15 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | catalogued as rs778628413, COSV59486260; called by mutect2, varscan2
- DNAI3 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV54002356; called by muse, mutect2, varscan2
- DNAJB2 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs750175376, COSV60676590; ClinVar: uncertain significance; called by mutect2, varscan2
- DNAJC5 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs769269113, COSV62671573; called by muse, varscan2
- DNAJC5 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV62671590; called by muse, varscan2
- DNAJC6 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757458350, COSV54774533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNMT1 | c.3109G>A p.A1037T | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as rs370786558; called by mutect2, varscan2
- DNMT3B | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs751976489, COSV52418291; called by mutect2, varscan2
- DNMT3B | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs572676072, COSV52418300; called by mutect2, varscan2
- DOCK11 | c.4004T>C p.V1335A | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52238640; called by muse, mutect2, varscan2
- DOCK2 | c.2702C>T p.A901V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771461758, COSV56957140; called by muse, mutect2, varscan2
- DOCK2 | c.3659A>G p.Y1220C | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1183186367, COSV56944674; called by muse, mutect2, varscan2
- DOCK4 | c.3767A>G p.H1256R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.482); catalogued as COSV69854553; called by muse, mutect2, varscan2
- DOCK4 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70319941; called by muse, varscan2
- DOCK7 | c.3893T>C p.V1298A (on ENST00000635253 / NM_001367561.1; = p.V1267A on NM_033407.3) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV52004565; called by muse, mutect2, varscan2
- DOCK7 | c.732G>A p.E244= | Splice Region (SNP) | VAF 13/126 reads (10%) | catalogued as COSV52004590; called by muse, mutect2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | catalogued as rs748134881; called by mutect2, varscan2
- DOK5 | c.76C>T p.R26* | Nonsense Mutation (SNP) | VAF 7/82 reads (9%) | catalogued as rs1359581597, COSV52819996; called by muse, mutect2
- DOP1A | c.1584A>T p.E528D | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.266); catalogued as COSV52710048; called by muse, mutect2, varscan2
- DOP1A | c.3041T>C p.V1014A | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52710060; called by muse, mutect2
- DOP1B | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV101215090; called by muse, mutect2, varscan2
- DOT1L | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs778851336, COSV67109312; called by mutect2, varscan2
- DPF3 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs749753214, COSV63500147, COSV99057249; called by mutect2, varscan2
- DPF3 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs558289942, COSV63500150; called by muse, mutect2, varscan2
- DPP10 | c.1730C>T p.T577I | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV100059362, COSV59684777; called by muse, mutect2, varscan2
- DPP6 | c.907G>A p.A303T (on ENST00000377770 / NM_001364500.2; = p.A241T on NM_001936.5) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs368694178; called by muse, mutect2, varscan2
- DPPA2 | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV72118064; called by muse, mutect2, varscan2
- DRD3 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.355); catalogued as rs201876283, COSV55680023, COSV99879740; called by muse, mutect2, varscan2
- DRD5 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs1481871870, COSV58577906; called by muse, mutect2, varscan2
- DRICH1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.913); catalogued as rs775895089, COSV58503806; called by muse, mutect2, varscan2
- DRP2 | c.1571G>A p.S524N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV65810278; called by mutect2, varscan2
- DSC1 | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as rs777889677, COSV57145486, COSV57152642; called by mutect2, varscan2
- DSCAML1 | c.4425C>T p.G1475= (on ENST00000321322; = p.G1415= on NM_020693.4) | Splice Region (SNP) | VAF 6/33 reads (18%) | catalogued as rs1475126838, COSV58390124; called by muse, mutect2, varscan2
- DSCAML1 | c.3456G>T p.Q1152H (on ENST00000321322; = p.Q1092H on NM_020693.4) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); catalogued as rs1487926569, COSV58390137; called by muse, mutect2, varscan2
- DSE | c.1859A>G p.D620G | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV59063790; called by muse, mutect2, varscan2
- DSG3 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs755487489, COSV57125339; called by muse, mutect2, varscan2
- DSP | c.7298G>A p.C2433Y | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65792603; called by muse, mutect2, varscan2
- DST | c.17223del p.K5741Nfs*2 (on ENST00000361203 / NM_001374722.1; = p.K3438Nfs*2 on NM_015548.5) | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs756726565; called by mutect2, varscan2
- DST | c.10985G>A p.R3662H (on ENST00000361203 / NM_001374722.1; = p.R1250H on NM_015548.5) | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.245); catalogued as rs755261768, COSV55007611; called by muse, mutect2, varscan2
- DST | c.2801T>C p.V934A (on ENST00000361203 / NM_001374722.1; = p.V608A on NM_001723.6) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55013375; called by muse, mutect2, varscan2
- DTL | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs768119065, COSV65342315; called by muse, mutect2, varscan2
- DTWD1 | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52071706; called by mutect2, varscan2
- DTX1 | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV57497260, COSV57500597; called by muse, mutect2
- DUOX2 | c.3365C>T p.A1122V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV66530777; called by muse, mutect2, varscan2
- DUSP10 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as COSV60457553; called by muse, mutect2, varscan2
- DUSP21 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV59133479; called by muse, mutect2, varscan2
- DXO | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374194980; called by muse, mutect2, varscan2
- DYNC1H1 | c.4674G>T p.K1558N | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV64136767; called by mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs772082432; called by mutect2, varscan2
- DYNC2H1 | c.12917dup p.N4306Kfs*18 | Frame Shift Ins (INS) | VAF 8/53 reads (15%) | catalogued as rs761970784; called by mutect2, pindel, varscan2
- DYRK1A | c.2236G>T p.E746* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as rs1487304397, COSV58705675, COSV58705803; called by muse, mutect2, varscan2
- E2F3 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 74/353 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318116281, COSV60897407; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs369293935; called by mutect2, varscan2
- EDEM3 | c.2338C>T p.R780W | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs749061615, COSV58924258; called by muse, mutect2, varscan2
- EDN1 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV65080718; called by muse, mutect2, varscan2
- EDNRB | c.298C>T p.R100C (on ENST00000377211 / NM_001201397.1; = p.R10C on NM_000115.5) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1204381719, COSV57522213; called by muse, varscan2
- EDRF1 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765217050, COSV61763807; called by mutect2, varscan2
- EDRF1 | c.1627C>T p.P543S (on ENST00000356792 / NM_001202438.2; = p.P509S on NM_015608.2) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as COSV61763815; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.295del p.X99_splice | Splice Site (DEL) | VAF 8/35 reads (23%) | catalogued as rs756314578; called by mutect2, pindel, varscan2
- EEF1AKMT4-ECE2 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62567739; called by muse, mutect2, varscan2
- EEF1B2 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV51909552; called by muse, mutect2, varscan2
- EEF2K | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs760638533, COSV53781617; called by mutect2, varscan2
- EFCAB1 | c.147T>A p.D49E | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50618280; called by muse, mutect2, varscan2
- EFCAB13 | c.1904del p.K635Rfs*5 | Frame Shift Del (DEL) | VAF 21/127 reads (17%) | catalogued as rs1310715596; called by mutect2, pindel, varscan2
- EFCAB5 | c.450del p.K150Nfs*17 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs760813779; called by mutect2, varscan2
- EFCAB7 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.04); catalogued as rs767896192, COSV52130371; called by muse, mutect2, varscan2
- EFTUD2 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs765588398, COSV68183025; called by muse, mutect2, varscan2
- EGR4 | c.1574G>T p.S525I (on ENST00000545030; = p.S422I on NM_001965.4) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1244510948, COSV71532006; called by muse, mutect2, varscan2
- EGR4 | c.898G>A p.A300T (on ENST00000545030; = p.A197T on NM_001965.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1345052758, COSV71532009; called by muse, varscan2
- EHMT1 | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as COSV58374722; called by muse, mutect2, varscan2
- EHMT2 | c.2563del p.L855Cfs*36 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as rs1377283633; called by mutect2, pindel, varscan2
- EIF2B4 | c.826G>A p.A276T (on ENST00000347454 / NM_001034116.2; = p.A275T on NM_015636.3) | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs1308215203, COSV52007746; called by muse, mutect2, varscan2
- EIF3M | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.099); catalogued as rs1295445179, COSV60072449; called by muse, mutect2, varscan2
- EIF4EBP1 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs751889248, COSV58774236; called by mutect2, varscan2
- EIF4ENIF1 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1383788713, COSV57515714; called by muse, mutect2
- EIF4G1 | c.935G>A p.R312H (on ENST00000346169 / NM_198241.3; = p.R116H on NM_004953.5) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as rs754009820, COSV59990810; called by muse, mutect2, varscan2
- EIF5B | c.107A>T p.E36V | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as COSV99176842; called by muse, mutect2, varscan2
- EIF5B | c.293del p.K98Rfs*83 | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | catalogued as rs769971529; called by mutect2, varscan2
- EIF5B | c.608del p.N203Ifs*10 | Frame Shift Del (DEL) | VAF 9/90 reads (10%) | catalogued as rs1176235101, COSV56813285; called by mutect2, varscan2
- EIF5B | c.856A>T p.T286S | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV56812871; called by muse, varscan2
- ELAPOR2 | c.1777G>A p.A593T (on ENST00000450689 / NM_001142749.3; = p.A426T on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV51886592; called by muse, varscan2
- ELF5 | c.200G>A p.R67H (on ENST00000312319 / NM_198381.2; = p.R57H on NM_001422.4) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs376593969; called by mutect2, varscan2
- ELK1 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55952849; called by muse, mutect2, varscan2
- ELMO1 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs776057144, COSV100164366, COSV60302254, COSV99068342; called by muse, mutect2, varscan2
- ELMO2 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.046); catalogued as rs756447733, COSV51682843; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 106/230 reads (46%) | catalogued as rs766700925; called by mutect2, varscan2
- ELOVL4 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs371760799; called by muse, mutect2, varscan2
- ELP1 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as rs137983175; called by muse, mutect2, varscan2
- EMC7 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1285458928, COSV56627748; called by muse, mutect2, varscan2
- EMILIN3 | c.504del p.S169Afs*45 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as rs777199500, COSV60037171; called by mutect2, pindel, varscan2
- ENC1 | c.374A>G p.D125G | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56629571; called by muse, mutect2, varscan2
- ENGASE | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs755437956, COSV56135401; called by mutect2, varscan2
- ENOSF1 | c.1058C>T p.A353V (on ENST00000340116 / NM_001354066.2; = p.A319V on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs756858370, COSV51890359; called by muse, mutect2, varscan2
- ENPEP | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.204); catalogued as rs770659499, COSV54450737; called by muse, mutect2, varscan2
- ENPEP | c.2165G>A p.G722D | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV54450767; called by muse, mutect2
- ENTPD3 | c.597+2T>C p.X199_splice | Splice Site (SNP) | VAF 77/199 reads (39%) | catalogued as rs1185536147, COSV57194322; called by muse, mutect2, varscan2
- ENTPD4 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as rs377657637; called by muse, mutect2, varscan2
- EP300 | c.6616G>T p.A2206S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.04); catalogued as COSV54332278; called by muse, mutect2, varscan2
- EPB41 | c.1467G>C p.L489F (on ENST00000343067 / NM_001166005.2; = p.L280F on NM_004437.4) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58046299; called by muse, mutect2, varscan2
- EPB41L3 | c.2157G>T p.Q719H | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV59452809; called by muse, mutect2, varscan2
- EPB41L4B | c.2376G>T p.E792D | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.069); catalogued as rs764903377, COSV101000857; called by muse, mutect2, varscan2
- EPB41L4B | c.383T>G p.L128R | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65796902; called by muse, mutect2, varscan2
- EPG5 | c.4597G>A p.A1533T | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs374899586; called by muse, mutect2, varscan2
- EPS8 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs577790263, COSV55528983; called by mutect2, varscan2
- EPS8L2 | c.1064T>C p.V355A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs142316225, COSV59346885; called by mutect2, varscan2
- ERAL1 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs780502321, COSV54739878; called by muse, mutect2, varscan2
- ERBIN | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV52316104; called by muse, mutect2, varscan2
- ERC1 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs1367706209, COSV61694667; called by muse, mutect2, varscan2
- ERCC6L | c.3259A>G p.M1087V | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV57820531; called by muse, mutect2, varscan2
- ERP29 | c.621dup p.K208Efs*22 | Frame Shift Ins (INS) | VAF 16/82 reads (20%) | catalogued as rs754819048; called by mutect2, pindel, varscan2
- ERVW-1 | c.810del p.F270Lfs*11 | Frame Shift Del (DEL) | VAF 23/107 reads (21%) | catalogued as rs1227584009; called by mutect2, pindel, varscan2
- ERVW-1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.096); catalogued as COSV101423809, COSV101423838; called by muse, mutect2, varscan2
- ESAM | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54034661; called by muse, mutect2, varscan2
- ESAM | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as rs777566375, COSV54034678; called by muse, mutect2, varscan2
- ESF1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1277847783, COSV52520081; called by muse, mutect2, varscan2
- ESRP1 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1198582850, COSV64409616; called by muse, mutect2, varscan2
- ESS2 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780626777, COSV52816941; called by muse, mutect2, varscan2
- ETF1 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1170118346, COSV62127293; called by muse, mutect2, varscan2
- ETNPPL | c.1390A>G p.I464V | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV56595700; called by muse, mutect2, varscan2
- ETNPPL | c.134A>G p.N45S | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.102); catalogued as COSV56595708; called by muse, mutect2, varscan2
- ETS1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs763167051, COSV60093421, COSV60093906; called by muse, mutect2, varscan2
- EVPL | c.3955C>T p.R1319C | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs375615208, COSV56910736; called by mutect2, varscan2
- EXO5 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1255458215, COSV56415704; called by muse, mutect2, varscan2
- EXOC2 | c.2129G>A p.R710H | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781679974, COSV57864773; called by muse, varscan2
- EXOC2 | c.1292G>T p.S431I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs1410402605, COSV57864783, COSV57870543; called by muse, mutect2, varscan2
- EXOC3 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.537); catalogued as rs767655668, COSV100154983, COSV59265873; called by mutect2, varscan2
- EXOC8 | c.1673A>G p.Y558C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.751); catalogued as COSV50478195; called by muse, mutect2, varscan2
- EXOSC7 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs146138646; called by mutect2, varscan2
- EXPH5 | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1395249817, COSV56198595; called by muse, mutect2, varscan2
- EXTL1 | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs750852433, COSV65337520; called by muse, mutect2, varscan2
- EXTL3 | c.2504C>T p.A835V | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55037927; called by muse, mutect2, varscan2
- EYA1 | c.1128del p.F376Lfs*4 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as rs1442231896; called by mutect2, pindel, varscan2
- EYA4 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.22); catalogued as rs764985361, COSV62051540; called by muse, varscan2
- EYS | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1352010833, COSV60984695; called by muse, mutect2, varscan2
- EZH2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 24/251 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as rs771352080, COSV57452692; called by mutect2, varscan2
- F9 | c.1157C>T p.T386I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as CM010286, CM940672, COSV54380153; called by muse, mutect2, varscan2
- FABP3 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.301); catalogued as rs200751117, COSV60002145; called by mutect2, varscan2
- FADS2 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as rs199900021, COSV53897508; called by muse, mutect2, varscan2
- FAF1 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV65638416; called by muse, mutect2, varscan2
- FAHD2A | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as COSV51978146; called by muse, mutect2, varscan2
- FAM110B | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.223); catalogued as rs768685073, COSV64065034; called by muse, mutect2, varscan2
- FAM114A1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.981); catalogued as rs764345278, COSV62672861; called by muse, mutect2, varscan2
- FAM118A | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1355505667, COSV53417090; called by muse, mutect2, varscan2
2,927 further variants in this file (1,972 protein-altering or splice-affecting, 886 silent, 69 other) are not listed here.
